Gene-level copy-number profile of tumor specimen TCGA-55-6987-01A from TCGA case TCGA-55-6987, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 77.7 years (28,382 days).
Specimen TCGA-55-6987-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.8285cfe6-2981-4cad-9e14-43abfbe0ae95.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-6987-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/85063847-6d72-4b28-a40c-db2dddd053ff

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 758; copy number 3: 5,562; copy number 4: 37,664; copy number 5: 8,642; copy number 6: 3,140; copy number 7: 2,773; copy number 8: 1,154; copy number 9: 2; copy number 10: 35; copy number 11: 43; copy number 12: 15; copy number 15: 12; copy number 17: 10; copy number 19: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-6987-01A-11D-1943-01): tumor purity 0.16, ploidy 2.31, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 122 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:53,304,536–55,064,852, 57 genes, copy number 10–17 (within-gene range 7–17): AL355483.2, LINC01771, AC119428.2, AC119428.1, LINC02812, SLC25A3P1, AL365445.1, DMRTB1, GLIS1, RNU7-95P, NDC1, AL049745.1, AL049745.2, YIPF1, DIO1, HSPB11, LRRC42, HNRNPA3P12, LDLRAD1, TMEM59, AL353898.3, TCEANC2, MIR4781, AL353898.1, AL353898.2, AL357673.1, CDCP2, AL357673.2, CYB5RL, MRPL37, SSBP3, SSBP3-AS1, AL161644.1, AL035415.1, AC099796.2, LINC02784, AC099796.1, HNRNPA1P63, ACOT11, FAM151A, AL590093.1, MROH7, MROH7-TTC4, TTC4, PARS2, TTC22, AC096536.1, LEXM, DHCR24, AC096536.3, AC096536.2, DHCR24-DT, AL590440.2, TMEM61, AL590440.1, BSND, PCSK9.
- chr1:75,122,518–76,066,349, 20 genes, copy number 12–19: AC099786.3, AC099786.1, LHX8, AC099786.2, RNU6-622P, SLC44A5, AC093156.1, RNU6-503P, AL096829.1, AL137803.1, ACADM, DLSTP1, RABGGTB, SNORD45C, SNORD45A, SNORD45B, MSH4, ASB17, AC092813.1, AC092813.2.
- chr1:77,194,825–79,522,203, 42 genes, copy number 11: AC093433.1, AC093433.2, AK5, AC095030.1, RNU7-8P, AC093575.1, ZZZ3, RNA5SP20, RN7SL370P, USP33, ACTG1P21, MIGA1, RNA5SP21, AC138392.1, NSRP1P1, HSPE1P25, NEXN-AS1, NEXN, FUBP1, DNAJB4, GIPC2, AC103591.3, AC103591.4, AC103591.2, RNU6-1102P, AC103591.1, RNA5SP22, RNFT1P2, MGC27382, PTGFR, AC096531.1, RNA5SP23, IFI44L, IFI44, AC104837.2, AC104837.1, ADGRL4, PSAT1P3, AL353651.2, AL353651.1, LINC02792, ADH5P2.
- chr8:121,612,116–121,641,440, 1 gene, copy number 11: HAS2.
- chr8:127,578,473–127,670,990, 2 genes, copy number 9 (within-gene range 4–9): AC104370.1, AC108925.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
